Surgical pathology report (de-identified scan), TCGA case TCGA-DY-A1DG, project TCGA-READ (Rectum Adenocarcinoma), tissue source site University Of Michigan, specimen TCGA-DY-A1DG-01A (Primary Tumor).

[page 1 of 2]
ICD-O-3
Adenocarcinoma, NOS 8140/3
Site Code: Rectum, NOS C20.9

1/10/11

lw

(First Tumor)

Tumor Site:	Rectum
Date of Cancer Sample Procurement:	
Histology:	Adenocarcinoma
Description of other histology:	
Grade:	Moderately Differentiated
Mucinous:	☒ No ☐ Yes ☐ Yes (Focal) ☐ Unknown
Signet Ring Feature:	☒ No ☐ Yes ☐ Yes (Focal) ☐ Unknown
Histologic Heterogeneity:	☒ No ☐ Yes ☐ Unknown
Host Response:	None
Crohn's like reaction	☒ None ☐ Yes ☐ Unknown
Plasma cell rich stroma	☐ No ☐ Yes ☐ Unknown
Growth Pattern:	☐ Expansile ☒ Invasive ☐ Expansile and Invasive ☐ Unknown
Inflammatory Bowel Disease	☒ No ☐ Yes ☐ Unknown
Angiolymphatic Invasion:	☐ No ☒ Yes ☐ Unknown
Mutator Phenotype:	☒ No ☐ Yes ☐ Unknown
Number of Slides	1
Garland Necrosis present:	☐ No ☒ Yes ☐ Yes (Focal) ☐ Unknown
TIL Cells / HPF	0
Pathologist Comment:	

[page 2 of 2]
(First Tumor)

Tumor Site:	[Redacted]		
Date of Cancer Sample Procurement:	[Redacted]		
Histology:	Adenocarcinoma		
Description of other histology:	[Redacted]		
Grade:	Moderately Differentiated		
Mucinous:	☒ No	☐ Yes	☐ Yes (Focal) ☐ Unknown
Signet Ring Feature:	☒ No	☐ Yes	☐ Yes (Focal) ☐ Unknown
Histologic Heterogeneity:	☒ No	☐ Yes	☐ Unknown
Host Response:	None		
Crohn's like reaction	☒ None	☐ Yes	☐ Unknown
Plasma cell rich stroma	☐ No	☐ Yes	☐ Unknown
Growth Pattern:	☐ Expansile	☒ Invasive	☐ Expansile and Invasive ☐ Unknown
Inflammatory Bowel Disease	☒ No	☐ Yes	☐ Unknown
Angiolymphatic Invasion:	☐ No	☒ Yes	☐ Unknown
Mutator Phenotype:	☒ No	☐ Yes	☐ Unknown
Number of Slides	1		
Garland Necrosis present:	☐ No	☒ Yes	☐ Yes (Focal) ☐ Unknown
TIL Cells / HPF	0		
Pathologist Comment:	[Redacted]		

Source: NCI Genomic Data Commons file ea7b0539-6f09-4668-8621-9b9441ea62b4 (TCGA-DY-A1DG.726DADA4-1C0E-46AF-B378-36DB1A3715B1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).